Gene-level copy-number profile of tumor specimen TCGA-CR-6467-01A from TCGA case TCGA-CR-6467, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 59.4 years (21,689 days).
Specimen TCGA-CR-6467-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.783e7284-a3f7-483f-9696-cb5af905c575.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-6467-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00296282-360d-46dd-ba78-7411e36cd3d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 6,657; copy number 2: 30,101; copy number 3: 20,222; copy number 4: 438; copy number 5: 2,387.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-6467-01A-11D-1869-01): tumor purity 0.66, ploidy 2.35, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:229,763,837–229,923,239, 1 gene (within-gene range 0–2): TRIP12.
- chr14:102,362,941–102,933,596, 13 genes (within-gene range 0–1): TECPR2, RNU6-244P, ANKRD9, MIR4309, LINC02323, RN7SL546P, RCOR1, RPL23AP11, Y_RNA, AL132801.1, TRAF3, RNU6-1316P, AMN.
- chr14:102,933,574–102,937,177, 1 gene: AL117209.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,387 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,648,075–97,358,478, 1,667 genes, copy number 5 (broad region; genes not listed).
- chr8:98,102,344–103,141,475, 128 genes, copy number 5 (broad region; genes not listed).
- chr8:104,590,733–145,066,685, 592 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,276. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
